BEATAML1.0 case 2186 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/3cf3a585-6d58-40fb-8eb7-6b1d6ccd6c9c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with myelodysplasia-related changes: ICD-O-3 morphology code: 9895/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,579 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (5 samples)
- Sample BA2099D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Samples BA2329D, BA2677D (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Samples BA2329R, BA2677R (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
